Gene-level copy-number profile of tumor specimen TCGA-95-8494-01A from TCGA case TCGA-95-8494, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Middle lobe, lung; AJCC pathologic stage: Stage IIA; Age at diagnosis: 67.8 years (24,773 days).
Specimen TCGA-95-8494-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.27508f09-f099-4840-88f1-317b5249b4ad.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-95-8494-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/104b3341-8547-49b6-b0dd-6ef13a5c7173

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 1; copy number 1: 741; copy number 2: 13,810; copy number 3: 11,056; copy number 4: 18,557; copy number 5: 8,803; copy number 6: 4,317; copy number 7: 814; copy number 8: 153; copy number 10: 451; copy number 11: 935; copy number 12: 12; copy number 14: 128; copy number 17: 36.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-95-8494-01A-11D-2322-01): tumor purity 0.53, ploidy 3.62, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,562 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:92,412,550–159,233,377, 1,386 genes, copy number 10–11 (broad region; genes not listed).
- chr12:17,083,531–17,167,790, 1 gene, copy number 12 (within-gene range 7–12): AC092110.1.
- chr12:17,383,352–18,648,416, 11 genes, copy number 12 (within-gene range 2–12): PSMC1P8, TIMM17BP1, AC048352.1, LINC02378, MIR3974, Y_RNA, RERGL, PIK3C2G, NDFIP1P1, AC092851.1, ZKSCAN7P1.
- chr12:19,404,045–19,720,801, 1 gene, copy number 17 (within-gene range 7–17): AEBP2.
- chr12:19,508,904–29,381,189, 163 genes, copy number 14–17 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 741. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
